Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A6G1, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A6G1-01A (Primary Tumor).

[page 1 of 5]
Gender

M

Date Of Birth

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Received

Time Reported

Order Number

Ordering Provider

Status

Final

Results

Source of Specimen

- A. TISSUE ANTERIOR TO PROSTATE-
- B. RIGHT PELVIC LYMPH NODES-
- C. LEFT PELVIC LYMPH NODES-
- D. UMBILICAL HERNIA-
- E. PROSTATE, SEMINAL VASICLES-

FINAL DIAGNOSIS:

- A. TISSUE ANTERIOR TO PROSTATE-
ADIPOSE TISSUE, NO MALIGNANCY SEEN.
- B. RIGHT PELVIC LYMPH NODES-
THREE LYMPH NODES, NO MALIGNANCY SEEN.
- C. LEFT PELVIC LYMPH NODES-
THREE LYMPH NODES, NO MALIGNANCY SEEN.
- D. UMBILICAL HERNIA-
MESOTHELIAL-LINED FIBROADIPOSE TISSUE CONSISTENT WITH HERNIA
SAC.
- E. PROSTATE, SEMINAL VASICLES-
ADENOCARCINOMA OF PROSTATE WITH MICROSCOPIC UNILATERAL
EXTENSION INTO EXTRAPROSTATIC SOFT TISSUE, see note.

TUMOR SITE: BILATERAL, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 40.0 GRAMS.

SIZE: 5.0 x 4.0 x 3.0 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 4 = 8/10.

Prepared for

Final

CKF *ICD-O-3* *814D3*

Adenocarcinoma, acinar

path *Adenocarcinoma NOS* *814D13*

Site: Prostate NOS *C61.9*

7/5/13

H2AA Discrepancy		☒
Print Malignancy History		☒

[page 2 of 5]
TERTIARY PATTERN: PRESENT, GLEASON GRADE 3/5.

SEVERITY IN EXTENT OF TUMOR: > 50% of examined tissue involvement.

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT PRESENT.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: pT3a, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT MARGINS OF PROSTATE, SOFT TISSUE, URETHRA AND BLADDER NECK.

EXTENSIVE ACUTE AND CHRONIC PROSTATITIS.

TWO PERIPROSTATIC LYMPH NODES, NEGATIVE FOR MALIGNANCY.

Note: Focally, the tumor extends into extraprostatic soft tissue in the right apex (B6). No carcinoma is seen at the inked margins.

Signature

(Case signed

Case Clinical Information

PROSTATE CANCER, UMBILICAL HERNIA

Gross Description

A. Received in formalin labeled with the patient's name and "tissue anterior to prostate" are multiple fragments of lobulated fat measuring 3 x 3 x 3 cm in compact aggregate. All material is submitted in A1-A4.

B. Received in formalin labeled with the patient's name and "right pelvic lymph nodes" is a fibroadipose fragment measuring 3 x 3 x 3 cm including a dominant lymph node bisected and submitted in B1-B2. Additional subtle areas of induration are submitted in B3.

C. Received in formalin labeled with the patient's name and

Prepared for

[page 3 of 5]
"left pelvic lymph nodes" are multiple fragments of fibroadipose tissue measuring 3.5 x 3.5 x 3.5 cm to include a dominant 4.5 cm lymph node. The dominant lymph node is totally submitted in C1-C3. Additional areas of induration are submitted in C4.

D. Received in formalin labeled with the patient's name and "umbilical hernia" is a fibro-membranous tissue measuring 2 x 2 x 1 cm thick. The entire specimen is submitted in D1.

E. Received in formalin labeled with the patient's name and "prostate and seminal vesicles" is a 40 gram specimen of a prostate gland with seminal vesicles, with the prostate itself measuring 5 cm right to left, 4 cm anterior to posterior and 3 cm superior to inferior. The right and left vas deferens measure 2 x 0.5 cm and 2 x 0.5 cm. The right and left seminal vesicles measure 2 x 1.2 x 0.8 cm and 2 x 1.2 x 0.8 cm in greater dimensions. The right side of the specimen has been inked blue, the left side black. Both the superior bladder margin and the inferior distal margin are amputated from the remainder of the specimen, sectioned parallel to the urethra and totally submitted anterior to posterior, with the remainder of the prostate submitted as well. Section code: E1-E6= apical margin of prostate entirely submitted anterior to posterior; first additional slice proceeding inferior to superior, anterior lobes in E7-E8; posterior lobes in E9-E10; second additional slice anterior lobes in E11-E12; posterior lobes in E13-E14; next additional slice anterior lobes in E15-E16; posterior lobes in E17-E18; remaining posterior lobes and area of seminal vesicles in E19-E20; E21=right seminal vesicle and vas resection margin; E22=left seminal vesicle and vas resection margin; E23-E25= bladder margin totally submitted parallel to urethra anterior to posterior. /

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1

Prepared for

[page 4 of 5]
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1

C. AA ROUTINE H&E X1 BLOCK.1
H&E X1

C. AA ROUTINE H&E X1 BLOCK.2
H&E X1

C. AA ROUTINE H&E X1 BLOCK.3
H&E X1

C. AA ROUTINE H&E X1 BLOCK.4
H&E X1

D. AA ROUTINE H&E X1 BLOCK
H&E X1

E. AA ROUTINE H&E X1 BLOCK.1
H&E X1

E. AA ROUTINE H&E X1 BLOCK.2
H&E X1

E. AA ROUTINE H&E X1 BLOCK.3
H&E

E. AA ROUTINE H&E X1 BLOCK.4
H&E

E. AA ROUTINE H&E X1 BLOCK.5
H&E X1 AA RECUT

E. AA ROUTINE H&E X1 BLOCK.6
H&E X1 A RECUTS

ROUTINE H&E X1 BLOCK.7

E. H&E X1 BLOCK.8
H&E X1

E. AA ROUTINE H&E X1 BLOCK.9
H&E X1

E. AA ROUTINE H&E X1 BLOCK.10
H&E X1

E. AA ROUTINE H&E X1 BLOCK.11
H&E X1

E. AA ROUTINE H&E X1 BLOCK.12
H&E X1 A RECUTS

E. AA ROUTINE H&E X1 BLOCK.13
H&E X1

E. AA ROUTINE H&E X1 BLOCK.14
H&E X1

E. AA ROUTINE H&E X1 BLOCK.15
H&E X1

E. AA ROUTINE H&E X1 BLOCK.16
H&E X1 AA RECUT

E. AA ROUTINE H&E X1 BLOCK.17
H&E X1

E. AA ROUTINE H&E X1 BLOCK.18
H&E X1

E. AA ROUTINE H&E X1 BLOCK.19

Prepared for:

[page 5 of 5]
H&E X1
E. AA ROUTINE H&E X1 BLOCK.20
H&E X1
E. AA ROUTINE H&E X1 BLOCK.21
H&E X1
E. AA ROUTINE H&E X1 BLOCK.22
H&E X1
E. AA ROUTINE H&E X1 BLOCK.23
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.24
H&E X1
E. AA ROUTINE H&E X1 BLOCK.25
H&E X1

Prepared for

Source: NCI Genomic Data Commons file 1836b9e8-dfb6-4f57-94d8-38ce4922fbf4 (TCGA-J4-A6G1.6758B6C3-61B6-4D4F-9018-CDC2E932ACC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).